MMRF case MMRF_2433 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b4ef7988-c15f-4c65-92f6-23413d3bdc35

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.9 years (19,701 days); ISS stage: II; Days to last known disease status: 714 days (2.0 years); Days to last follow up: 714 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 248 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 248 days; Days to treatment end: 248 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 5.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 89.7 mg/dL; Immunoglobulin G 73.2 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.57 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 28 g/L; Total Protein 11.6 g/dL; Glucose 5.01 mmol/L.
- Day 59 (ECOG 0): M Protein 3.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 45.5 mg/dL; Immunoglobulin G 47.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.91 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 8.7 g/dL; Glucose 7.1 mmol/L.
- Day 153 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.88 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.67 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 246 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.9 mg/dL; Immunoglobulin G 7.71 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 6 mmol/L.
- Day 315 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.74 mg/dL; Immunoglobulin G 4.26 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.14 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.28 mmol/L.
- Day 461 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 7.89 g/L; Immunoglobulin A 1.34 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.23 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 560 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 9.36 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.78 mmol/L.
- Day 644 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 8.83 g/L; Immunoglobulin A 2.2 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.33 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.53 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 714 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 9.82 g/L; Immunoglobulin A 2.48 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.74 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.

Other clinical attributes
- Day -6: Weight: 74 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2433_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_2433_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
